Somatic mutation profile of tumor specimen TARGET-30-PATDXC-01A (aliquot TARGET-30-PATDXC-01A-01D) from TARGET case TARGET-30-PATDXC, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 4.5 years (1,659 days).
Specimen TARGET-30-PATDXC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 03400149-6c5b-4855-86dc-c862a1dbc027.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATDXC-10A (Blood Derived Normal), aliquot TARGET-30-PATDXC-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e7f8d1fd-4518-406d-9c22-8402b5d3ed8c

The open-access MAF lists 19 somatic variants for this specimen: 17 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 11, Nonsense Mutation 5, Silent 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B3GNT7 | c.733G>A p.V245I | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1362488543, COSV55006196; called by muse, mutect2, varscan2
- CA1 | c.319G>T p.E107* | Nonsense Mutation (SNP) | VAF 19/61 reads (31%) | catalogued as COSV56278125; called by muse, mutect2, varscan2
- CEACAM16 | c.478G>T p.A160S | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.6); catalogued as COSV69186552; called by muse, mutect2, varscan2
- IRF2BP1 | c.1119C>A p.N373K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.021); catalogued as COSV56193276; called by muse, mutect2, varscan2
- LRP1B | c.9778G>T p.D3260Y | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV67203879, COSV67220409; called by muse, mutect2, varscan2
- LRRIQ1 | c.3331G>T p.E1111* | Nonsense Mutation (SNP) | VAF 25/133 reads (19%) | catalogued as COSV67828814; called by muse, mutect2, varscan2
- OR14C36 | c.315dup p.V106Cfs*14 | Frame Shift Ins (INS) | VAF 16/70 reads (23%) | catalogued as rs761899382; called by mutect2, varscan2
- PLA2G6 | c.1268C>T p.A423V | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs199636953; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR1 | c.3043C>T p.R1015C | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs139006437, COSV62099806; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SARDH | c.811G>T p.A271S | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.792); catalogued as COSV53832869; called by muse, mutect2, varscan2
- STK36 | c.2768C>A p.A923E | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0.054); catalogued as COSV55325596; called by muse, mutect2, varscan2
- TDRD6 | c.3620A>T p.E1207V | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.642); catalogued as COSV60174934; called by muse, mutect2, varscan2
- TOPORS | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs777936936, COSV62116633; called by muse, mutect2, varscan2
- TPTE2 | c.1289T>A p.L430* (on ENST00000400230 / NM_199254.2; = p.L353* on NM_130785.3) | Nonsense Mutation (SNP) | VAF 6/37 reads (16%) | catalogued as COSV55019423; called by muse, mutect2
- TSPAN17 | c.911C>G p.T304S | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as COSV53779889; called by muse, mutect2
- WDR72 | c.511C>T p.Q171* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as COSV64744350; called by muse, mutect2
- PLPP3 | c.659G>A p.W220* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | called by muse, mutect2
- FRS3 | c.375C>T p.P125= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as rs202019125, COSV52484578; called by muse, mutect2, varscan2
- KATNAL2 | c.1044C>T p.S348= (on ENST00000356157 / NM_001353899.1; = p.S276= on NM_031303.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
